Gene-level copy-number profile of tumor specimen ALCH-B0EN-TTP1-A from ALCHEMIST case ALCH-B0EN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.9 years (21,143 days).
Specimen ALCH-B0EN-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d592c544-9983-4d32-9be5-a6620ca65986.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0EN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/adb43cde-8302-41b9-9e19-cf6728293d3b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 3,130; copy number 2: 52,223; copy number 3: 2,965; copy number 4: 67.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:46,394,317–46,413,848, 1 gene: FAAH.
- chr1:121,573,946–121,580,524, 1 gene: LINC01691.
- chr2:132,147,591–132,263,042, 5 genes (within-gene range 0–2): ANKRD30BL, RNU6-1132P, RNA5-8SP5, MIR663B, CDC27P1.
- chr3:121,049,640–121,049,715, 1 gene (within-gene range 0–1): MIR5682.
- chr10:95,141,925–95,173,187, 2 genes: AL157834.4, AL157834.3.
- chr15:64,701,248–64,719,602, 1 gene (within-gene range 0–2): AC100830.1.
- chr16:89,737,549–89,816,657, 1 gene (within-gene range 0–3): FANCA.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662, AC006504.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,838. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
